Somatic mutation profile of tumor specimen TCGA-C5-A1M8-01A (aliquot TCGA-C5-A1M8-01A-21D-A13W-08) from TCGA case TCGA-C5-A1M8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 43.4 years (15,848 days).
Specimen TCGA-C5-A1M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7049a52d-a9ed-4a75-a013-f096d8d90067.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A1M8-10A (Blood Derived Normal), aliquot TCGA-C5-A1M8-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e96fd50-7286-4159-bf82-a3e424db3f68

The open-access MAF lists 63 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 43, Silent 14, Nonsense Mutation 4, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC131160.1 | c.933C>T p.A311= | Splice Region (SNP) | VAF 50/143 reads (35%) | catalogued as COSV100226291; called by muse, mutect2, varscan2
- AMY2B | c.1457A>T p.D486V | Missense Mutation (SNP) | VAF 254/586 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV63714429; called by muse, mutect2, varscan2
- ATP10A | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280281587, COSV63515020; called by muse, mutect2, varscan2
- AXIN2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 81/223 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61056352, COSV61057569; called by muse, mutect2, varscan2
- BBOX1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54189971; called by muse, varscan2
- BFAR | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 80/197 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.855); catalogued as COSV55492824, COSV99902147; called by muse, varscan2
- BPTF | c.5753G>A p.R1918K | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV58833620; called by muse, mutect2, varscan2
- CECR2 | c.2255G>T p.G752V (on ENST00000342247 / NM_001290047.2; = p.G569V on NM_001290046.1) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV52838055; called by muse, mutect2, varscan2
- CHD8 | c.1733G>A p.R578H (on ENST00000646647 / NM_001170629.2; = p.R299H on NM_020920.4) | Missense Mutation (SNP) | VAF 95/276 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1452630110, COSV67869962; called by muse, mutect2, varscan2
- CNNM2 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV63995665; called by muse, mutect2, varscan2
- COG3 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1219540725, COSV63071764; called by muse, mutect2, varscan2
- COL22A1 | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV57328671; called by muse, mutect2
- CTIF | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56481221; called by muse, mutect2, varscan2
- DNMBP | c.1840C>T p.R614C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759618419, COSV60620007; called by muse, mutect2, varscan2
- EIF3E | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0.216); catalogued as COSV55201119, COSV55202044, COSV55202459; called by muse, mutect2, varscan2
- GABRA1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50099939, COSV50108440; called by muse, mutect2, varscan2
- GXYLT1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1011244027, COSV55134119; called by muse, mutect2, varscan2
- IGDCC3 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV60076988; called by muse, mutect2, varscan2
- IGHG3 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs752126457; called by muse, mutect2, varscan2
- LAMA5 | c.5164C>T p.R1722W | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs375141745; called by muse, mutect2, varscan2
- LRP1B | c.13025G>A p.S4342N | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67198112; called by muse, mutect2, varscan2
- MIOX | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.567); catalogued as rs771073069, COSV53312190; called by muse, mutect2, varscan2
- MUC4 | c.2222C>T p.A741V | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.494); catalogued as COSV100641447; called by muse, mutect2
- MYCBP2 | c.1894G>A p.D632N (on ENST00000357337; = p.D670N on NM_015057.5) | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV62012857; called by muse, mutect2, varscan2
- MYH8 | c.3206C>A p.T1069K | Missense Mutation (SNP) | VAF 78/192 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV67961628; called by muse, mutect2, varscan2
- MYOM3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV58391491; called by muse, mutect2, varscan2
- OBSL1 | c.1075G>A p.V359M | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763498145, COSV54713269; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCBP3 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV68407040; called by muse, mutect2, varscan2
- PHKA1 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781996165, COSV100263132, COSV59803513; called by muse, mutect2, varscan2
- PHLDB3 | c.1812C>G p.F604L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52668395; called by muse, mutect2, varscan2
- PPTC7 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.069); catalogued as COSV62825881; called by muse, mutect2, varscan2
- PSMB8 | c.172G>A p.G58S (on ENST00000374882 / NM_148919.4; = p.G54S on NM_004159.5) | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1221043396, COSV62754029; called by muse, mutect2, varscan2
- PTPN13 | c.5225C>T p.S1742L (on ENST00000411767 / NM_080683.3; = p.S1723L on NM_006264.3) | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV57404224; called by muse, mutect2, varscan2
- PTPN14 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 79/172 reads (46%) | catalogued as rs772180365, COSV65282278; called by muse, mutect2, varscan2
- RABGAP1L | c.1426G>C p.G476R | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV52283229; called by muse, mutect2, varscan2
- RASA3 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61865138; called by muse, mutect2, varscan2
- REL | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV54363042, COSV54364574; called by muse, mutect2, varscan2
- RNF19B | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1178632602, COSV52387067; called by muse, mutect2, varscan2
- SPANXN5 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 131/144 reads (91%) | catalogued as COSV64968681; called by muse, mutect2, varscan2
- SPEF2 | c.1976G>T p.S659I | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV61545759; called by muse, mutect2, varscan2
- XRN2 | c.2755C>G p.P919A | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1272800788, COSV65868739; called by muse, mutect2, varscan2
- ZNF232 | c.1175G>T p.C392F | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51502768; called by muse, mutect2, varscan2
- ZNF350 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs753952350, COSV54708112; called by muse, mutect2, varscan2
- ZNF493 | c.1373C>G p.S458* | Nonsense Mutation (SNP) | VAF 29/59 reads (49%) | catalogued as rs1033858784, COSV62749455, COSV62751631; called by muse, mutect2, varscan2
- ZNF773 | c.643G>T p.G215W | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56587925; called by muse, mutect2, varscan2
- ZNF773 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56587941, COSV99989153; called by muse, mutect2, varscan2
- ZSCAN1 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | catalogued as COSV56602747, COSV56608373; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.627_640del p.L210Cfs*6 | Frame Shift Del (DEL) | VAF 10/14 reads (71%) | called by mutect2, varscan2
- TRAV14DV4 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 101/221 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- ABCB10 | c.1359G>A p.S453= | Silent (SNP) | VAF 48/124 reads (39%) | catalogued as rs770732387, COSV60620288; called by muse, mutect2, varscan2
- C18orf54 | c.756C>T p.P252= | Silent (SNP) | VAF 105/240 reads (44%) | catalogued as rs374556847, COSV55619144; called by muse, mutect2, varscan2
- CEP95 | c.1794G>A p.K598= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV73608836; called by muse, mutect2, varscan2
- FAM47C | c.93G>A p.A31= | Silent (SNP) | VAF 21/27 reads (78%) | catalogued as rs868908339, COSV63724809; called by muse, mutect2, varscan2
- FLVCR1 | c.672C>T p.I224= | Silent (SNP) | VAF 48/95 reads (51%) | catalogued as COSV63133921; called by muse, mutect2, varscan2
- LRRC74A | c.828G>A p.L276= | Silent (SNP) | VAF 82/156 reads (53%) | catalogued as COSV53608496; called by muse, mutect2, varscan2
- PEAK1 | c.1467C>T p.L489= | Silent (SNP) | VAF 221/330 reads (67%) | catalogued as rs754934083, COSV56931083; called by muse, mutect2, varscan2
- POLR2A | c.2937C>G p.L979= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- SELE | c.1311G>A p.P437= | Silent (SNP) | VAF 52/156 reads (33%) | catalogued as rs144324234; called by muse, mutect2, varscan2
- TRAV8-2 | c.66G>A p.S22= | Silent (SNP) | VAF 57/124 reads (46%) | called by muse, mutect2, varscan2
- UBE4B | c.2229C>T p.G743= (on ENST00000343090 / NM_001105562.3; = p.G614= on NM_006048.5) | Silent (SNP) | VAF 66/147 reads (45%) | catalogued as rs371708780; called by muse, mutect2, varscan2
- VWA7 | c.2520C>T p.T840= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as rs754463009, COSV65172753; called by muse, mutect2, varscan2
- ZAN | c.2079G>A p.T693= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs778233082, COSV61806620; called by muse, mutect2, varscan2
- ZNF644 | c.3168T>C p.H1056= | Silent (SNP) | VAF 65/159 reads (41%) | catalogued as COSV61346506; called by muse, mutect2, varscan2
